Somatic mutation profile of tumor specimen ALCH-B0FM-TTP1-A (aliquot ALCH-B0FM-TTP1-A-1-0-D-A709-36) from ALCHEMIST case ALCH-B0FM, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 66.3 years (24,218 days).
Specimen ALCH-B0FM-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 750ffbb5-a4a0-4338-8a97-abff7664a6be.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B0FM-NB1-A (Blood Derived Normal), aliquot ALCH-B0FM-NB1-A-1-0-D-A709-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b552a268-47ee-4294-9a4b-b408b890e6cc

The open-access MAF lists 1,234 somatic variants for this specimen: 795 protein-altering or splice-affecting, 260 silent, 179 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 681, Silent 260, Intron 94, Nonsense Mutation 72, RNA 22, 5'UTR 21, 3'UTR 21, Frame Shift Del 13, 5'Flank 12, Splice Site 12, Splice Region 11, 3'Flank 9.

Variants (750 of 1,234; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.919+1G>C p.X307_splice | Splice Site (SNP) | VAF 119/286 reads (42%) | hotspot (GDC flag); catalogued as rs1131691039, CD920913, CS107068, CS120864, COSV52683145, COSV52775982, COSV52814989; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.10514C>T p.S3505F | Missense Mutation (SNP) | VAF 31/457 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.013); catalogued as rs1219379363; called by muse, mutect2
- ABCC8 | c.4500C>A p.S1500R | Missense Mutation (SNP) | VAF 33/111 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.031); catalogued as CM150911, COSV56848952; called by muse, mutect2, varscan2
- AC090517.4 | c.305C>T p.S102L | Missense Mutation (SNP) | VAF 20/471 reads (4%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); catalogued as rs1162873316, COSV50999248; called by muse, mutect2
- ACKR4 | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 78/654 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.791); catalogued as rs770290540, COSV51442366; called by muse, mutect2, varscan2
- ADAMTS9 | c.4798C>T p.R1600W | Missense Mutation (SNP) | VAF 118/291 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs746159542, COSV55786573, COSV55787118; called by muse, mutect2, varscan2
- ADAMTSL1 | c.97G>C p.D33H | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV52822067; called by muse, mutect2
- ADAMTSL1 | c.677-1G>C p.X226_splice | Splice Site (SNP) | VAF 16/279 reads (6%) | catalogued as COSV52820085, COSV99442612; called by muse, mutect2
- ADGRB3 | c.1927C>G p.Q643E | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as COSV101001591; called by muse, mutect2, varscan2
- AGMO | c.652C>G p.P218A | Missense Mutation (SNP) | VAF 80/321 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs1562483889; called by muse, mutect2, varscan2
- AHNAK | c.16537C>T p.L5513F | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs762031877; called by muse, mutect2, varscan2
- AKT3 | c.1237G>A p.V413I | Missense Mutation (SNP) | VAF 35/218 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs769299773; called by muse, mutect2, varscan2
- ALB | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 44/445 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs58624704, COSV55739298; called by muse, mutect2, varscan2
- ANKRD12 | c.5291C>T p.S1764F | Missense Mutation (SNP) | VAF 18/183 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.406); catalogued as COSV50820596; called by muse, mutect2, varscan2
- ANKRD18B | c.853dup p.R285Kfs*29 | Frame Shift Ins (INS) | VAF 40/214 reads (19%) | catalogued as rs755445457; called by mutect2, varscan2
- ANKRD50 | c.1628C>G p.S543* | Nonsense Mutation (SNP) | VAF 42/444 reads (9%) | catalogued as COSV101538885; called by muse, mutect2
- ANXA6 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 32/189 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766534449; called by muse, mutect2, varscan2
- APLNR | c.538C>A p.Q180K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.6); PolyPhen benign (0.036); catalogued as rs1367901533; called by muse, mutect2, varscan2
- ARL15 | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.037); catalogued as COSV72291371; called by muse, mutect2, varscan2
- ARPP21 | c.1868C>T p.S623L | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.05); catalogued as COSV51793888; called by muse, mutect2
- ASXL1 | c.2832G>C p.L944F | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated, low confidence (0.33); PolyPhen probably damaging (0.981); catalogued as COSV60119338; called by muse, mutect2
- ATMIN | c.1246G>A p.D416N | Missense Mutation (SNP) | VAF 37/352 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as rs748928269; called by muse, mutect2, varscan2
- ATP10D | c.2086G>C p.E696Q | Missense Mutation (SNP) | VAF 7/110 reads (6%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.449); catalogued as COSV99905652; called by muse, mutect2
- ATP13A4 | c.2786C>A p.S929* | Nonsense Mutation (SNP) | VAF 30/1008 reads (3%) | catalogued as COSV61319082; called by muse, mutect2
- ATP7A | c.499C>G p.Q167E | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as CM942029; called by muse, mutect2
- ATR | c.4678G>T p.D1560Y | Missense Mutation (SNP) | VAF 114/522 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as COSV63385253, COSV63387928; called by muse, varscan2
- BCL2L12 | c.133C>G p.R45G | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.03); catalogued as COSV55862547; called by muse, mutect2, varscan2
- BCO2 | c.1739G>C p.*580Sext*13 | Nonstop Mutation (SNP) | VAF 20/222 reads (9%) | catalogued as COSV63063492; called by muse, mutect2
- BPTF | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 11/226 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58842009; called by muse, mutect2
- BPTF | c.7403G>T p.R2468L | Missense Mutation (SNP) | VAF 110/407 reads (27%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.137); catalogued as COSV100076081; called by muse, mutect2, varscan2
- C16orf46 | c.412del p.Q138Rfs*66 | Frame Shift Del (DEL) | VAF 25/116 reads (22%) | catalogued as rs1567574033; called by mutect2, pindel, varscan2
- CABIN1 | c.5989C>T p.P1997S | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.057); catalogued as rs1195295266; called by muse, mutect2
- CADM3 | c.218G>A p.G73E (on ENST00000368125 / NM_001127173.3; = p.G107E on NM_021189.5) | Missense Mutation (SNP) | VAF 13/263 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV63684218; called by muse, mutect2
- CCDC126 | c.417C>G p.I139M | Missense Mutation (SNP) | VAF 18/111 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.134); catalogued as rs768302932; called by muse, mutect2, varscan2
- CCDC141 | c.1945A>C p.M649L | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs1373582209; called by muse, mutect2, varscan2
- CCDC78 | c.1185C>A p.F395L | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99557225; called by muse, mutect2, varscan2
- CCNB1 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56510207; called by muse, mutect2
- CCNB3 | c.1798C>A p.H600N | Missense Mutation (SNP) | VAF 75/142 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1233683255; called by muse, varscan2
- CCSER1 | c.1475G>A p.R492K | Missense Mutation (SNP) | VAF 28/396 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV100392800; called by muse, mutect2
- CDCP1 | c.1512C>G p.I504M | Missense Mutation (SNP) | VAF 32/290 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs143267287; called by muse, mutect2, varscan2
- CDH9 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 42/388 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.89); catalogued as rs1326476376, COSV99143944; called by muse, mutect2, varscan2
- CEMIP2 | c.1736C>G p.S579* | Nonsense Mutation (SNP) | VAF 24/342 reads (7%) | catalogued as COSV65487216; called by muse, mutect2
- CEP290 | c.6025C>G p.L2009V | Missense Mutation (SNP) | VAF 17/310 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.061); catalogued as rs1428066297; called by muse, mutect2
- CEP76 | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 35/360 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.847); catalogued as COSV50865707; called by muse, mutect2, varscan2
- CHRM2 | c.697C>T p.P233S | Missense Mutation (SNP) | VAF 24/513 reads (5%) | SIFT tolerated (0.54); PolyPhen benign (0.01); catalogued as COSV57769588; called by muse, mutect2
- CHRNA2 | c.161C>T p.S54L | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs761493925; called by muse, mutect2
- CHTF18 | c.737C>T p.S246L | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as rs772010365, COSV50100292; called by muse, mutect2, varscan2
- CIC | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.346); catalogued as rs1361309406, COSV50660196, COSV99359024; called by muse, mutect2, varscan2
- CIC | c.283G>C p.E95Q | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.011); catalogued as COSV50554919; called by muse, varscan2
- CIC | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 30/294 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99360214; called by muse, mutect2
- CKAP2 | c.428C>T p.T143I (on ENST00000378037 / NM_001098525.2; = p.T142I on NM_018204.5) | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs370214081; called by muse, mutect2, varscan2
- CLEC4M | c.169T>A p.S57T | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.718); catalogued as rs866432975; called by muse, mutect2, varscan2
- CLIP1 | c.3518C>T p.S1173L (on ENST00000620786 / NM_001247997.1; = p.S1162L on NM_002956.2) | Missense Mutation (SNP) | VAF 16/347 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.079); catalogued as COSV100212315, COSV56799753; called by muse, mutect2
- CMTM2 | c.688G>C p.E230Q | Missense Mutation (SNP) | VAF 16/312 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.031); catalogued as COSV51748495; called by muse, mutect2
- COL14A1 | c.2757C>G p.F919L | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV52856439; called by muse, mutect2, varscan2
- COL17A1 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 25/395 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100793048; called by muse, mutect2
- CPNE6 | c.1472G>A p.C491Y | Missense Mutation (SNP) | VAF 46/124 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.065); catalogued as COSV99393632; called by muse, mutect2, varscan2
- CYP27C1 | c.766C>A p.L256M | Missense Mutation (SNP) | VAF 25/230 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.139); catalogued as COSV58868542; called by muse, mutect2, varscan2
- DAOA | c.436G>T p.E146* | Nonsense Mutation (SNP) | VAF 16/131 reads (12%) | catalogued as COSV61601631; called by muse, mutect2
- DBX2 | c.863G>T p.S288I | Missense Mutation (SNP) | VAF 18/282 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV60338231; called by muse, mutect2
- DCC | c.3970G>A p.E1324K | Missense Mutation (SNP) | VAF 40/576 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.322); catalogued as rs377756608; called by muse, mutect2
- DCST1 | c.1808C>A p.A603E | Missense Mutation (SNP) | VAF 16/332 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV55059738; called by muse, mutect2
- DEFB129 | c.451G>C p.E151Q | Missense Mutation (SNP) | VAF 32/570 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV55731783, COSV99857336; called by muse, mutect2
- DGKB | c.358C>G p.R120G | Missense Mutation (SNP) | VAF 76/330 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.037); catalogued as COSV99340130; called by muse, mutect2, varscan2
- DIAPH2 | c.3175C>G p.L1059V | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61277732; called by muse, mutect2
- DLG2 | c.811G>A p.V271I | Missense Mutation (SNP) | VAF 22/204 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.139); catalogued as COSV99713025; called by muse, mutect2, varscan2
- DNA2 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 16/416 reads (4%) | catalogued as rs1398180154, COSV64427384; called by muse, mutect2
- DNAH7 | c.10462C>T p.Q3488* | Nonsense Mutation (SNP) | VAF 13/276 reads (5%) | catalogued as COSV100416962; called by muse, mutect2
- DNAH8 | c.1538C>A p.P513H | Missense Mutation (SNP) | VAF 115/501 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59453960; called by muse, mutect2, varscan2
- DOCK4 | c.644G>C p.G215A | Missense Mutation (SNP) | VAF 27/490 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV70323885; called by muse, mutect2
- DOCK9 | c.5661G>C p.E1887D (on ENST00000376460 / NM_001366676.2; = p.E1888D on NM_015296.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/560 reads (4%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV59630702; called by muse, mutect2
- DPF2 | c.1045G>A p.D349N | Missense Mutation (SNP) | VAF 84/278 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373186765, COSV52890310; called by muse, mutect2, varscan2
- DRD2 | c.532G>C p.D178H | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV100669385; called by muse, mutect2, varscan2
- ELAPOR2 | c.1954G>C p.E652Q (on ENST00000450689 / NM_001142749.3; = p.E485Q on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT tolerated (0.73); PolyPhen benign (0.131); catalogued as rs959557760; called by muse, mutect2
- ENPP2 | c.2369C>T p.S790F (on ENST00000075322 / NM_001040092.3; = p.S842F on NM_006209.5) | Missense Mutation (SNP) | VAF 45/405 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1367139354, COSV50012622, COSV99307957; called by muse, mutect2, varscan2
- EP400 | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.509); catalogued as rs770352911; called by muse, mutect2
- EPHA10 | c.328C>G p.R110G | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780244767; called by muse, mutect2, varscan2
- EPSTI1 | c.947G>C p.W316S (on ENST00000398762 / NM_001330543.2; = p.W305S on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/462 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100553269; called by muse, mutect2, varscan2
- ERCC6 | c.4216G>A p.E1406K | Missense Mutation (SNP) | VAF 186/646 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs145622432; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ERCC6 | c.420C>G p.L140= | Splice Region (SNP) | VAF 18/354 reads (5%) | catalogued as COSV63388041; called by muse, mutect2
- ESPN | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as COSV64703868; called by muse, mutect2, varscan2
- ESRRA | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.019); catalogued as rs369905424; called by mutect2, varscan2
- F11 | c.449C>A p.T150K | Missense Mutation (SNP) | VAF 108/334 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1340928778, CM062613; called by muse, mutect2, varscan2
- F13B | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 32/479 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.759); catalogued as rs748341394, COSV66373444; called by muse, mutect2
- FAH | c.781C>T p.P261S | Missense Mutation (SNP) | VAF 22/369 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99930608; called by muse, mutect2
- FAM102A | c.823G>T p.V275L (on ENST00000373095 / NM_001035254.3; = p.V133L on NM_203305.2) | Missense Mutation (SNP) | VAF 68/127 reads (54%) | SIFT tolerated (0.47); PolyPhen benign (0.07); catalogued as rs750737789; called by muse, mutect2, varscan2
- FAM120A | c.2309C>G p.S770* | Nonsense Mutation (SNP) | VAF 27/286 reads (9%) | catalogued as COSV52912930; called by muse, mutect2
- FAM13C | c.1501C>G p.L501V | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.693); catalogued as rs1453155142, COSV53248944; called by muse, mutect2
- FAM228B | c.17G>T p.S6I | Missense Mutation (SNP) | VAF 12/225 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.888); catalogued as rs1449099855; called by muse, mutect2
- FAT1 | c.5737C>T p.Q1913* | Nonsense Mutation (SNP) | VAF 54/182 reads (30%) | catalogued as rs760573361; called by muse, mutect2, varscan2
- FCRLA | c.646C>T p.Q216* (on ENST00000367959; = p.Q193* on NM_032738.4) | Nonsense Mutation (SNP) | VAF 100/231 reads (43%) | catalogued as COSV52685269; called by muse, mutect2, varscan2
- FLG | c.1196C>A p.A399D | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.9); catalogued as rs774370689, COSV64253185; called by muse, mutect2, varscan2
- FLG2 | c.231G>A p.M77I | Missense Mutation (SNP) | VAF 90/413 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs867371117; called by muse, mutect2, varscan2
- FLNA | c.5240C>T p.S1747L (on ENST00000369850 / NM_001110556.2; = p.S1739L on NM_001456.3) | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs1557176526; ClinVar: uncertain significance; called by muse, mutect2
- FLNA | c.4483G>A p.E1495K | Missense Mutation (SNP) | VAF 12/151 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as COSV61053576; called by muse, mutect2
- FLT1 | c.1709G>C p.G570A | Missense Mutation (SNP) | VAF 25/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56741286; called by muse, mutect2
- FOXD4L5 | c.293C>A p.A98E | Missense Mutation (SNP) | VAF 82/315 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV101073243; called by muse, mutect2, varscan2
- GALNT18 | c.544C>A p.P182T | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1413611108; called by muse, mutect2
- GANC | c.1380G>C p.K460N | Missense Mutation (SNP) | VAF 37/396 reads (9%) | PolyPhen probably damaging (0.936); catalogued as COSV58808504; called by muse, mutect2
- GLIS3 | c.2320G>A p.E774K | Missense Mutation (SNP) | VAF 47/538 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs758121146, COSV60938169, COSV60938434; called by muse, mutect2
- GNAI3 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 66/169 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63984340; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1176G>C p.M392I | Missense Mutation (SNP) | VAF 57/151 reads (38%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as rs1445146211; called by muse, mutect2, varscan2
- GOLIM4 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 18/598 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.036); catalogued as rs1180486095; called by muse, mutect2
- GON4L | c.622C>G p.Q208E | Missense Mutation (SNP) | VAF 22/638 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.034); catalogued as COSV55198610; called by muse, mutect2
- GSDMB | c.799G>A p.D267N (on ENST00000418519 / NM_001165958.1; = p.D245N on NM_018530.2) | Missense Mutation (SNP) | VAF 43/273 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.074); catalogued as rs764152715; called by muse, mutect2, varscan2
- GSTA1 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 42/616 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV58015178; called by muse, mutect2
- GTF3C3 | c.298G>C p.E100Q | Missense Mutation (SNP) | VAF 24/352 reads (7%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.08); catalogued as COSV55833576; called by muse, mutect2
- GYG2 | c.141C>G p.I47M | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV58550619; called by muse, mutect2, varscan2
- HES4 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1288380786; called by muse, mutect2, varscan2
- HGH1 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 36/295 reads (12%) | catalogued as rs1215194536; called by muse, mutect2, varscan2
- HIP1 | c.3046G>C p.E1016Q | Missense Mutation (SNP) | VAF 11/244 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as COSV61188850; called by muse, mutect2
- HSD17B11 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 22/244 reads (9%) | catalogued as rs777162512, COSV64154324; called by muse, mutect2, varscan2
- IDE | c.2185C>T p.L729F | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.118); catalogued as rs1270312493; called by muse, mutect2
- INO80E | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as rs749965250, COSV99663323; called by muse, mutect2, varscan2
- ISM1 | c.985G>A p.E329K | Missense Mutation (SNP) | VAF 13/450 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52605152; called by muse, mutect2
- ITPK1 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.392); catalogued as rs767945252, COSV50894878, COSV50896361; called by muse, mutect2, varscan2
- IVL | c.1383G>C p.K461N | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100908061, COSV64216157; called by muse, mutect2
- KANK4 | c.1153C>T p.R385* | Nonsense Mutation (SNP) | VAF 16/189 reads (8%) | catalogued as rs1311359487, COSV62985750; called by muse, mutect2
- KARS1 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 25/434 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.429); catalogued as rs1217745713; called by muse, mutect2
- KCTD16 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs865986167; called by muse, mutect2, varscan2
- KCTD8 | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 48/430 reads (11%) | catalogued as COSV63589513, COSV63591967; called by muse, mutect2, varscan2
- KEAP1 | c.404G>T p.R135L | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.528); catalogued as COSV50302633, COSV99407963; called by muse, mutect2, varscan2
- KIF15 | c.3913A>G p.K1305E | Missense Mutation (SNP) | VAF 58/185 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs934154104; called by muse, mutect2, varscan2
- KIF18B | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 18/196 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.056); catalogued as rs756864529; called by muse, mutect2
- KIF21B | c.4426A>G p.K1476E (on ENST00000422435 / NM_001252100.2; = p.K1463E on NM_017596.4) | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as rs1437697718; called by muse, mutect2, varscan2
- KLHL40 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 14/119 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as rs775821505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KRT23 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 100/526 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs973494814, COSV52928966; called by muse, mutect2, varscan2
- KRTAP19-6 | c.145C>A p.R49S | Missense Mutation (SNP) | VAF 22/257 reads (9%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as COSV61843805, COSV99068199; called by muse, mutect2
- KRTAP19-7 | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 92/437 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100603211; called by muse, mutect2, varscan2
- L3HYPDH | c.697G>A p.D233N | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as COSV99070629; called by muse, mutect2
- LAMA4 | c.3388C>G p.Q1130E (on ENST00000230538 / NM_001105206.3; = p.Q1123E on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/474 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV57898945; called by muse, mutect2
- LETM2 | c.239C>T p.S80F (on ENST00000379957 / NM_001286819.2; = p.S33F on NM_144652.3) | Missense Mutation (SNP) | VAF 29/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs376807655; called by muse, mutect2
- LGI1 | c.1014C>G p.F338L | Missense Mutation (SNP) | VAF 19/205 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.405); catalogued as rs1442418989, COSV65057861; called by muse, mutect2
- LIPC | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 66/333 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773742252, COSV54422434; called by muse, mutect2, varscan2
- LRP2 | c.11281G>A p.E3761K | Missense Mutation (SNP) | VAF 17/506 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55548323; called by muse, mutect2
- LRSAM1 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.138); catalogued as COSV55939311; called by muse, mutect2
- LRTM2 | c.815C>G p.A272G | Missense Mutation (SNP) | VAF 26/49 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs775095786; called by muse, mutect2, varscan2
- LVRN | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as COSV63497863; called by muse, mutect2, varscan2
- LYST | c.11353C>T p.R3785C | Missense Mutation (SNP) | VAF 48/1092 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV67706190; called by muse, mutect2
- MAGEA11 | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 25/228 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as rs868960320, COSV60758687; called by muse, mutect2, varscan2
- MAGEB10 | c.202C>A p.Q68K | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.053); catalogued as COSV100775235; called by muse, mutect2, varscan2
- MAGED1 | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 11/217 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.523); catalogued as COSV100431353; called by muse, mutect2
- MAGI3 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.156); catalogued as COSV56835720; called by muse, mutect2
- MAOB | c.599C>T p.S200L | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs12850496, COSV65206276; called by muse, mutect2, varscan2
- MAP11 | c.724+1G>C p.X242_splice | Splice Site (SNP) | VAF 89/225 reads (40%) | catalogued as rs1171539063; called by muse, mutect2, varscan2
- MAP2 | c.1769G>T p.S590I | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52284493; called by muse, mutect2, varscan2
- MAP3K21 | c.2882C>T p.P961L | Missense Mutation (SNP) | VAF 36/240 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as rs1334553353; called by muse, mutect2, varscan2
- MAPK1 | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 20/324 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53185671; called by muse, mutect2
- MAPK4 | c.1700C>A p.A567E | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.468); catalogued as COSV68542423; called by muse, mutect2
- MCMDC2 | c.940A>G p.T314A | Missense Mutation (SNP) | VAF 12/275 reads (4%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV58034368; called by muse, mutect2
- MECOM | c.1900C>T p.P634S (on ENST00000468789 / NM_001105078.4; = p.P822S on NM_004991.4) | Missense Mutation (SNP) | VAF 47/252 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV52965270; called by muse, mutect2, varscan2
- MED1 | c.3824C>G p.S1275* | Nonsense Mutation (SNP) | VAF 12/216 reads (6%) | catalogued as COSV56123794; called by muse, mutect2
- MED13 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 15/269 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV67262996; called by muse, mutect2
- MEP1A | c.550C>G p.L184V | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.17); catalogued as COSV57918074; called by muse, mutect2
- METTL2A | c.360G>C p.K120N | Missense Mutation (SNP) | VAF 16/477 reads (3%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV61045012; called by muse, mutect2
- MKI67 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 9/76 reads (12%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.626); catalogued as COSV64077456; called by muse, mutect2, varscan2
- MORC1 | c.2002G>A p.E668K | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.115); catalogued as COSV51732628; called by muse, mutect2
- MROH2A | c.2609C>T p.S870F | Missense Mutation (SNP) | VAF 8/240 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1335912161; called by muse, mutect2
- MS4A14 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 14/340 reads (4%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55735090, COSV55736401; called by muse, mutect2
- MTHFD1 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 16/488 reads (3%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV53703801; called by muse, mutect2
- MUC6 | c.4664G>A p.R1555K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV70149430; called by muse, mutect2, varscan2
- MXRA8 | c.338C>T p.S113L | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.343); catalogued as COSV58511074; called by muse, mutect2
- MYO10 | c.4096G>A p.A1366T | Missense Mutation (SNP) | VAF 42/267 reads (16%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as COSV99944906; called by muse, varscan2
- MYO15A | c.10388C>T p.S3463L | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1236735016, COSV52766181; called by muse, mutect2
- MYO18B | c.3683G>T p.G1228V | Missense Mutation (SNP) | VAF 62/298 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV59127556; called by muse, mutect2, varscan2
- MYO1G | c.1567G>T p.D523Y | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs762799551; called by muse, mutect2, varscan2
- NBEAL2 | c.7717G>C p.E2573Q | Missense Mutation (SNP) | VAF 14/252 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV99436469; called by muse, mutect2
- NCAM2 | c.961G>T p.V321L | Missense Mutation (SNP) | VAF 47/232 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV53099152; called by muse, mutect2, varscan2
- NECTIN3 | c.1066C>G p.L356V | Missense Mutation (SNP) | VAF 131/540 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as rs995780840; called by muse, mutect2, varscan2
- NFATC4 | c.1470G>C p.K490N | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51603517; called by muse, mutect2, varscan2
- NLRP5 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 45/277 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.006); catalogued as rs762196512; called by muse, mutect2, varscan2
- NR3C2 | c.1154C>G p.S385* | Nonsense Mutation (SNP) | VAF 22/264 reads (8%) | catalogued as COSV60989648; called by muse, mutect2
- NRXN1 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 58/214 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as rs376814357, COSV58441080; called by muse, mutect2, varscan2
- NTSR1 | c.165C>A p.D55E | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.057); catalogued as COSV65138460; called by muse, mutect2, varscan2
- NUSAP1 | c.1026G>C p.L342F | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV99530687; called by muse, mutect2
- OR2L13 | c.900G>A p.M300I | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV100813835; called by muse, mutect2
- OR4A15 | c.388G>C p.E130Q | Missense Mutation (SNP) | VAF 44/263 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV59033892; called by muse, mutect2, varscan2
- OR4D5 | c.506G>T p.C169F | Missense Mutation (SNP) | VAF 50/352 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58308315; called by muse, mutect2, varscan2
- OR52D1 | c.539C>A p.T180K | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1466343271, COSV59488471; called by muse, mutect2, varscan2
- OR5H15 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 15/374 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.315); catalogued as COSV100736792; called by muse, mutect2
- OR6X1 | c.880G>T p.E294* | Nonsense Mutation (SNP) | VAF 8/52 reads (15%) | catalogued as COSV60009808; called by mutect2, varscan2
- OTOF | c.2644G>A p.D882N (on ENST00000272371 / NM_194248.3; = p.D135N on NM_004802.4) | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as COSV99718233; called by muse, mutect2, varscan2
- PAQR9 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs373875132; called by muse, mutect2
- PARP15 | c.1999C>G p.Q667E (on ENST00000464300 / NM_001113523.3; = p.Q433E on NM_152615.2) | Missense Mutation (SNP) | VAF 8/160 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as rs911855571, COSV59974450; called by muse, mutect2
- PCDHA9 | c.2345C>A p.S782Y | Missense Mutation (SNP) | VAF 11/208 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.326); catalogued as rs531990107, COSV65326788; called by muse, mutect2
- PCDHB16 | c.1489C>T p.H497Y | Missense Mutation (SNP) | VAF 31/201 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.251); catalogued as rs1554282277; called by muse, mutect2, varscan2
- PCDHB4 | c.1831C>A p.P611T | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.984); catalogued as rs782081599; called by muse, mutect2, varscan2
- PCK1 | c.1019C>T p.S340L | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV60128198; called by muse, mutect2
- PDE4DIP | c.6880C>T p.Q2294* | Nonsense Mutation (SNP) | VAF 26/320 reads (8%) | catalogued as rs1553634665, COSV57734642; called by muse, mutect2
- PIAS1 | c.734G>T p.R245L | Missense Mutation (SNP) | VAF 64/431 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs764996234, COSV51030416, COSV99986783; called by muse, mutect2, varscan2
- PITRM1 | c.820G>A p.E274K | Missense Mutation (SNP) | VAF 104/282 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as rs1408646329; called by muse, mutect2, varscan2
- PKHD1 | c.9535C>T p.L3179F | Missense Mutation (SNP) | VAF 32/1230 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs897671588, COSV100583205; called by muse, mutect2
- PKHD1L1 | c.7859G>T p.G2620V | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1339418245, COSV65742455; called by muse, mutect2
- PLCL1 | c.2035G>T p.D679Y | Missense Mutation (SNP) | VAF 34/201 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV70830965; called by muse, mutect2, varscan2
- PLEC | c.11143G>A p.G3715S (on ENST00000322810 / NM_201380.4; = p.G3605S on NM_000445.5) | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs782222673, COSV59690153; ClinVar: uncertain significance; called by muse, mutect2
- PLSCR4 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 44/385 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV104421051; called by muse, mutect2, varscan2
- POTEJ | c.1972C>T p.Q658* | Nonsense Mutation (SNP) | VAF 46/816 reads (6%) | catalogued as rs1386921742; called by muse, mutect2
- PRMT1 | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.003); catalogued as rs371508595; called by muse, mutect2, varscan2
- PROX1 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.995); catalogued as COSV54780598; called by muse, mutect2, varscan2
- PRPF4B | c.2641G>A p.E881K | Missense Mutation (SNP) | VAF 9/207 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61783412; called by muse, mutect2
- PRR11 | c.500G>C p.G167A | Missense Mutation (SNP) | VAF 46/636 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs780016733; called by muse, mutect2
- PSD | c.2019G>C p.M673I | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV50041590; called by muse, mutect2
- PSG2 | c.543G>A p.W181* | Nonsense Mutation (SNP) | VAF 24/396 reads (6%) | catalogued as COSV61545792; called by muse, mutect2
- PSMA7 | c.127C>T p.L43F | Missense Mutation (SNP) | VAF 17/348 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs1342054323; called by muse, mutect2
- PTCHD4 | c.931G>C p.E311Q | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.74); catalogued as rs79417370; called by muse, mutect2, varscan2
- PTGES | c.23T>C p.M8T | Missense Mutation (SNP) | VAF 33/57 reads (58%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1355824049; called by muse, mutect2, varscan2
- PTPRN2 | c.1046G>A p.R349Q | Missense Mutation (SNP) | VAF 21/260 reads (8%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs748134802, COSV67030209; called by muse, mutect2
- PWWP3B | c.1322G>C p.R441T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61801433; called by muse, mutect2
- RAB39B | c.622G>C p.E208Q | Missense Mutation (SNP) | VAF 12/114 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV101035001; called by muse, mutect2, varscan2
- RAB3GAP2 | c.1696A>G p.T566A | Missense Mutation (SNP) | VAF 187/509 reads (37%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs1279009682; called by muse, mutect2, varscan2
- RBM17 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs1418879722, COSV65914405; called by muse, mutect2
- RBM20 | c.667C>G p.P223A | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as rs1394222373; called by muse, mutect2
- RECQL4 | c.3331G>C p.E1111Q | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.908); catalogued as COSV100020899; called by muse, mutect2, varscan2
- REG3A | c.68A>C p.Q23P | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV59409866; called by muse, mutect2, varscan2
- RGS22 | c.2383C>T p.R795* | Nonsense Mutation (SNP) | VAF 17/279 reads (6%) | catalogued as rs1210721109; called by muse, mutect2
- RHBDD1 | c.560C>T p.S187L | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs1237638288, COSV100392283; called by muse, mutect2
- RINT1 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 38/547 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs139214585; ClinVar: likely benign; called by muse, mutect2
- RYR2 | c.14067G>C p.K4689N | Missense Mutation (SNP) | VAF 19/312 reads (6%) | SIFT tolerated (0.21); PolyPhen benign (0.075); catalogued as rs1197613873; called by muse, mutect2
- RYR2 | c.14345C>T p.T4782I | Missense Mutation (SNP) | VAF 60/445 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV63660589; called by muse, mutect2, varscan2
- RYR3 | c.9712G>A p.D3238N (on ENST00000389232; = p.D3239N on NM_001036.6) | Missense Mutation (SNP) | VAF 48/443 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs200275874, COSV66780962; called by muse, mutect2, varscan2
- SCN1A | c.1966G>C p.G656R | Missense Mutation (SNP) | VAF 62/179 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.18); catalogued as COSV100321378; called by muse, mutect2, varscan2
- SCN9A | c.4063G>A p.D1355N (on ENST00000303354; = p.D1344N on NM_002977.3) | Missense Mutation (SNP) | VAF 19/609 reads (3%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV57626623; called by muse, mutect2
- SERPINI2 | c.867-1G>C p.X289_splice | Splice Site (SNP) | VAF 10/210 reads (5%) | catalogued as COSV52985642; called by muse, mutect2
- SHANK1 | c.5556del p.L1855Wfs*12 | Frame Shift Del (DEL) | VAF 16/54 reads (30%) | catalogued as rs762156350; called by mutect2, varscan2
- SHF | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as rs1194059421; called by muse, mutect2
- SIDT2 | c.1471G>T p.A491S | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99637756; called by muse, mutect2, varscan2
- SIX3 | c.385G>A p.E129K | Missense Mutation (SNP) | VAF 27/196 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as CM086934; called by muse, mutect2, varscan2
- SLC22A4 | c.113C>A p.S38* | Nonsense Mutation (SNP) | VAF 10/214 reads (5%) | catalogued as rs1490660372; called by muse, mutect2
- SLC35D1 | c.295C>G p.P99A | Missense Mutation (SNP) | VAF 15/393 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.742); catalogued as rs1396029996; called by muse, mutect2
- SLC39A12 | c.1706C>T p.S569L (on ENST00000377369 / NM_001145195.2; = p.S532L on NM_152725.3) | Missense Mutation (SNP) | VAF 20/322 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101069791; called by muse, mutect2
- SLC6A3 | c.1354A>G p.I452V | Missense Mutation (SNP) | VAF 95/380 reads (25%) | SIFT tolerated (0.91); PolyPhen benign (0.006); catalogued as COSV99549146; called by muse, mutect2, varscan2
- SLTM | c.1108G>A p.G370R | Missense Mutation (SNP) | VAF 33/263 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99989032; called by muse, mutect2, varscan2
- SMG7 | c.2419C>G p.Q807E | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV100750385; called by muse, mutect2, varscan2
- SNIP1 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); catalogued as COSV99055619; called by muse, mutect2, varscan2
- SON | c.2558C>T p.S853F | Missense Mutation (SNP) | VAF 72/456 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs780531078; called by muse, varscan2
- SPAG16 | c.1312G>T p.A438S | Missense Mutation (SNP) | VAF 87/376 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.811); catalogued as rs747474099, COSV100531553; called by muse, mutect2, varscan2
- STAC2 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 71/198 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.283); catalogued as rs1340799404; called by muse, mutect2, varscan2
- STAT3 | c.1541C>A p.S514Y | Missense Mutation (SNP) | VAF 28/575 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99232863; called by muse, mutect2
- STAT6 | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 30/366 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs767265892, COSV55670576; called by muse, mutect2
- STYXL2 | c.1238G>A p.R413K | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1254164426; called by mutect2, varscan2
- SYNE1 | c.14191G>A p.D4731N (on ENST00000367255 / NM_182961.4; = p.D4660N on NM_033071.3) | Missense Mutation (SNP) | VAF 51/158 reads (32%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV99558313; called by muse, mutect2, varscan2
- SYNM | c.1217C>T p.S406L | Missense Mutation (SNP) | VAF 39/633 reads (6%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs782165312, COSV100152353; called by muse, mutect2
- SYNM | c.3017C>G p.S1006* | Nonsense Mutation (SNP) | VAF 16/262 reads (6%) | catalogued as rs781849411; called by muse, mutect2
- TAC1 | c.180G>T p.K60N | Missense Mutation (SNP) | VAF 66/280 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV59987341; called by muse, mutect2, varscan2
- TAOK1 | c.1303C>T p.R435* | Nonsense Mutation (SNP) | VAF 28/315 reads (9%) | catalogued as COSV55597764; called by muse, mutect2
- TAOK2 | c.3494G>C p.S1165T | Missense Mutation (SNP) | VAF 9/168 reads (5%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.001); catalogued as rs1297635790; called by muse, mutect2
- TAS2R4 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 11/152 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.338); catalogued as rs1160530758, COSV99924690; called by muse, mutect2
- TBC1D12 | c.484G>C p.E162Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV56552469; called by muse, mutect2
- TBC1D5 | c.1861C>G p.Q621E | Missense Mutation (SNP) | VAF 15/95 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99509678; called by muse, mutect2, varscan2
- TBX22 | c.998C>G p.S333C | Missense Mutation (SNP) | VAF 24/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64786710; called by muse, mutect2
- TCEAL2 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as COSV61197643; called by muse, mutect2, varscan2
- TDRD9 | c.428C>G p.S143C | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1209898681; called by muse, mutect2
- TEK | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 23/673 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.129); catalogued as rs1296261695; called by muse, mutect2
- TENM2 | c.8056G>A p.D2686N (on ENST00000518659 / NM_001122679.2; = p.D2447N on NM_001080428.3) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.335); catalogued as rs754345348; called by muse, mutect2, varscan2
- TENM3 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 23/399 reads (6%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.14); catalogued as COSV69318593; called by muse, mutect2
- TFEC | c.961C>G p.L321V | Missense Mutation (SNP) | VAF 16/259 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV99624639; called by muse, mutect2
- TGFBR3 | c.565G>A p.E189K | Missense Mutation (SNP) | VAF 16/476 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99282373; called by muse, mutect2
- TMC5 | c.2296C>T p.L766F (on ENST00000396229 / NM_001105248.1; = p.L520F on NM_024780.5) | Missense Mutation (SNP) | VAF 23/341 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1300666947, COSV54910825; called by muse, mutect2
- TMEM132D | c.3119C>G p.S1040* | Nonsense Mutation (SNP) | VAF 11/70 reads (16%) | catalogued as COSV67159241, COSV67160414; called by muse, mutect2, varscan2
- TMEM14B | c.24-1G>C p.X8_splice | Splice Site (SNP) | VAF 24/390 reads (6%) | catalogued as COSV65356047; called by muse, mutect2
- TMEM156 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.52); PolyPhen benign (0.104); catalogued as COSV60745307; called by muse, mutect2
- TNN | c.430G>A p.G144S | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as rs1310445733; called by muse, varscan2
- TNR | c.3938G>A p.G1313E | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1235552937; called by muse, mutect2, varscan2
- TP53BP1 | c.223G>A p.D75N | Missense Mutation (SNP) | VAF 33/291 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.932); catalogued as rs1049302691; called by muse, mutect2, varscan2
- TP53I3 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 7/149 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1284158197, COSV53187653; called by muse, mutect2
- TPM3 | c.198G>C p.K66N | Missense Mutation (SNP) | VAF 30/767 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV55136393; called by muse, mutect2
- TPO | c.1657G>A p.D553N | Missense Mutation (SNP) | VAF 21/321 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.133); catalogued as rs377390255; called by muse, mutect2
- TRAPPC8 | c.3590A>G p.D1197G | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs759248247; called by muse, mutect2, varscan2
- TRMT10C | c.248C>G p.S83* | Nonsense Mutation (SNP) | VAF 83/285 reads (29%) | catalogued as rs749199440; called by muse, mutect2, varscan2
- TTN | c.89348C>A p.A29783D (on ENST00000591111; = p.A22359D on NM_003319.4) | Missense Mutation (SNP) | VAF 20/110 reads (18%) | PolyPhen benign (0.238); catalogued as COSV100634234; called by muse, mutect2
- TTN | c.65514del p.K21839Nfs*30 (on ENST00000591111; = p.K14415Nfs*30 on NM_003319.4) | Frame Shift Del (DEL) | VAF 56/241 reads (23%) | catalogued as COSV100598186; called by mutect2, pindel, varscan2
- TTN | c.27458A>G p.Y9153C (on ENST00000591111; = p.Y8226C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/195 reads (31%) | PolyPhen benign (0.306); catalogued as rs781236320; called by muse, mutect2, varscan2
- TTN | c.13161G>T p.R4387S (on ENST00000591111; = p.R4341S on NM_003319.4) | Missense Mutation (SNP) | VAF 14/101 reads (14%) | PolyPhen benign (0.033); catalogued as COSV59883629; called by muse, mutect2, varscan2
- UBE2F | c.172G>A p.D58N | Missense Mutation (SNP) | VAF 12/342 reads (4%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.99); catalogued as COSV99800410; called by muse, mutect2
- UBN2 | c.3121G>A p.A1041T | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs568483690; called by muse, mutect2
- UNC13C | c.1550C>A p.S517* | Nonsense Mutation (SNP) | VAF 50/136 reads (37%) | catalogued as COSV52922175; called by muse, mutect2, varscan2
- USH2A | c.5885G>T p.R1962I | Missense Mutation (SNP) | VAF 336/929 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV56326245; called by muse, mutect2, varscan2
- USP16 | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 9/121 reads (7%) | catalogued as COSV100537798; called by muse, mutect2
- WDFY4 | c.8551C>A p.Q2851K | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs1216438391; called by muse, mutect2, varscan2
- WHRN | c.2542-1G>C p.X848_splice | Splice Site (SNP) | VAF 11/206 reads (5%) | catalogued as COSV54330253; called by muse, mutect2
- XAB2 | c.1244G>A p.R415H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1290081390, COSV50379050; called by muse, mutect2, varscan2
- XIRP2 | c.9142C>A p.R3048S (on ENST00000628543; = p.R3223S on NM_152381.6) | Missense Mutation (SNP) | VAF 68/399 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs371935411; called by muse, mutect2, varscan2
- YLPM1 | c.332C>G p.P111R | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); catalogued as rs755872108; called by muse, mutect2
- YY1 | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1172486228; called by muse, mutect2
- ZFHX4 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 22/362 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.288); catalogued as COSV50967493; called by muse, mutect2
- ZKSCAN1 | c.548C>T p.S183L | Missense Mutation (SNP) | VAF 50/302 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.025); catalogued as rs759540374, COSV60872986; called by muse, mutect2, varscan2
- ZNF140 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 27/167 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV60579703; called by muse, mutect2, varscan2
- ZNF229 | c.158C>G p.S53C | Missense Mutation (SNP) | VAF 13/345 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.01); catalogued as rs1446824809, COSV99350219; called by muse, mutect2
- ZNF519 | c.760G>T p.G254* | Nonsense Mutation (SNP) | VAF 23/102 reads (23%) | catalogued as COSV73913271; called by muse, mutect2, varscan2
- ZNF559 | c.1472G>T p.R491L | Missense Mutation (SNP) | VAF 78/368 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.251); catalogued as COSV57837350; called by muse, mutect2, varscan2
- ZNF648 | c.1141C>A p.R381S | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.046); catalogued as COSV60570187; called by muse, mutect2, varscan2
- ZNF667 | c.75G>T p.Q25H | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.505); catalogued as rs775707772; called by muse, mutect2, varscan2
- ZNF853 | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1271623840; called by muse, mutect2, varscan2
- AARS2 | c.2902A>T p.T968S | Missense Mutation (SNP) | VAF 90/367 reads (25%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- ABAT | c.992G>C p.G331A | Missense Mutation (SNP) | VAF 8/155 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ABCC1 | c.1625C>A p.S542Y | Missense Mutation (SNP) | VAF 40/350 reads (11%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ABHD1 | c.43G>A p.D15N | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2
- ACAP2 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 78/540 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACCSL | c.1120A>T p.S374C | Missense Mutation (SNP) | VAF 29/112 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACP7 | c.958C>A p.L320I | Missense Mutation (SNP) | VAF 30/248 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ACSM5 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 74/373 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- ADAM21 | c.852A>T p.Q284H | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.6); PolyPhen benign (0.007); called by muse, mutect2
- ADAMTS13 | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.57); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ADAMTS18 | c.1928G>T p.C643F | Missense Mutation (SNP) | VAF 39/304 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADAMTS9 | c.3612G>A p.M1204I | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.296); called by muse, mutect2
- ADAMTSL1 | c.1546G>A p.E516K | Missense Mutation (SNP) | VAF 19/317 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ADGRB3 | c.1487G>C p.G496A | Missense Mutation (SNP) | VAF 84/398 reads (21%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADGRB3 | c.3544G>C p.A1182P | Missense Mutation (SNP) | VAF 106/328 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- ADGRV1 | c.8549G>C p.R2850T | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADRB1 | c.354C>G p.I118M | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- AFDN | c.4753G>T p.D1585Y | Missense Mutation (SNP) | VAF 18/264 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.564); called by muse, mutect2
- AHNAK | c.17471C>A p.T5824N | Missense Mutation (SNP) | VAF 42/141 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- AKAP9 | c.3856G>A p.D1286N | Missense Mutation (SNP) | VAF 26/535 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- AKNA | c.2467G>A p.E823K | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.023); called by muse, mutect2
- AKNA | c.627C>G p.D209E | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2
- ALAS2 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 107/207 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ALDOC | c.91C>G p.L31V | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ALG11 | c.503T>A p.V168D | Missense Mutation (SNP) | VAF 101/431 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- AMACR | c.784G>C p.D262H | Missense Mutation (SNP) | VAF 19/171 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- AMPD1 | c.1462T>C p.W488R | Missense Mutation (SNP) | VAF 67/217 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANK1 | c.2102G>T p.G701V | Missense Mutation (SNP) | VAF 71/380 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ANKRA2 | c.374C>T p.P125L | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ANKRD26 | c.3503A>T p.Q1168L | Missense Mutation (SNP) | VAF 89/266 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- ANO3 | c.2162C>T p.S721L | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT tolerated (0.41); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- ANO4 | c.134C>G p.S45* | Nonsense Mutation (SNP) | VAF 54/210 reads (26%) | called by muse, mutect2, varscan2
- AOPEP | c.1933G>A p.E645K (on ENST00000375315 / NM_001193329.1; = p.E546K on NM_032823.5) | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.211); called by muse, mutect2
- APOB | c.3143C>A p.T1048N | Missense Mutation (SNP) | VAF 22/452 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2
- APOB | c.508A>G p.T170A | Missense Mutation (SNP) | VAF 157/397 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- APOB | c.155A>T p.Y52F | Missense Mutation (SNP) | VAF 36/627 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARHGAP31 | c.173C>T p.S58L | Missense Mutation (SNP) | VAF 24/696 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- ARHGEF2 | c.1759G>T p.E587* (on ENST00000361247 / NM_001162383.2; = p.E559* on NM_004723.3 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 14/233 reads (6%) | called by muse, mutect2
- ARSL | c.892C>G p.L298V | Missense Mutation (SNP) | VAF 19/232 reads (8%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.662); called by muse, mutect2
- ASPM | c.3295G>T p.G1099C | Missense Mutation (SNP) | VAF 87/268 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- ATF6 | c.1130G>C p.R377T | Missense Mutation (SNP) | VAF 19/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ATG16L2 | c.559G>C p.E187Q | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- ATG2A | c.5599C>G p.Q1867E | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.6); called by muse, mutect2, varscan2
- ATP1A2 | c.803del p.I268Kfs*15 | Frame Shift Del (DEL) | VAF 46/248 reads (19%) | called by mutect2, pindel, varscan2
- ATP2A2 | c.615G>C p.K205N | Missense Mutation (SNP) | VAF 53/532 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.349); called by muse, mutect2
- ATP6V0A1 | c.864G>C p.K288N | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.734); called by muse, mutect2
- ATP6V0E1 | c.150C>G p.L50= | Splice Region (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- B4GALT4 | c.447G>C p.Q149H | Missense Mutation (SNP) | VAF 12/309 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- BANF2 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 11/289 reads (4%) | SIFT tolerated (0.62); PolyPhen benign (0.074); called by muse, mutect2
- BCDIN3D | c.166C>T p.R56* | Nonsense Mutation (SNP) | VAF 6/121 reads (5%) | called by muse, mutect2
- BLOC1S6 | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 16/494 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- BMP2K | c.3476C>G p.S1159C | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.936); called by muse, mutect2
- BRD8 | c.430G>C p.D144H | Missense Mutation (SNP) | VAF 11/206 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2
- BRWD3 | c.4027G>A p.E1343K | Missense Mutation (SNP) | VAF 13/209 reads (6%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.074); called by muse, mutect2
- BTG1 | c.42G>C p.E14D | Missense Mutation (SNP) | VAF 16/186 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2
- BTRC | c.214G>A p.E72K (on ENST00000370187 / NM_033637.4; = p.E36K on NM_003939.5) | Missense Mutation (SNP) | VAF 11/198 reads (6%) | SIFT tolerated, low confidence (0.32); PolyPhen possibly damaging (0.678); called by muse, mutect2
- C21orf62 | c.452G>C p.R151T | Missense Mutation (SNP) | VAF 10/144 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- C2CD6 | c.737A>T p.Y246F | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- C8A | c.1378G>C p.E460Q | Missense Mutation (SNP) | VAF 57/523 reads (11%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- C9orf43 | c.1357G>C p.E453Q | Missense Mutation (SNP) | VAF 30/330 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.276); called by muse, mutect2
- CACNA1B | c.6415C>A p.P2139T | Missense Mutation (SNP) | VAF 93/151 reads (62%) | SIFT tolerated (0.35); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- CACNA1C | c.3271T>A p.W1091R | Missense Mutation (SNP) | VAF 69/163 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CALB1 | c.431C>G p.A144G | Missense Mutation (SNP) | VAF 54/225 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- CARMIL3 | c.1567G>A p.A523T | Missense Mutation (SNP) | VAF 18/137 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- CATSPERG | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 16/53 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CBLIF | c.558G>C p.K186N | Missense Mutation (SNP) | VAF 60/477 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.384); called by muse, mutect2, varscan2
- CCDC141 | c.1112G>C p.R371T | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.383); called by muse, mutect2
- CCDC40 | c.313G>T p.G105W | Missense Mutation (SNP) | VAF 85/427 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.717); called by muse, mutect2, varscan2
- CCER2 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2
- CCN3 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 43/305 reads (14%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- CD163L1 | c.2157G>A p.W719* | Nonsense Mutation (SNP) | VAF 137/361 reads (38%) | called by muse, mutect2, varscan2
- CDCA2 | c.2219C>T p.S740F | Missense Mutation (SNP) | VAF 13/135 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.003); called by muse, mutect2
- CDCP1 | c.1286C>G p.S429* | Nonsense Mutation (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- CDK5RAP2 | c.3095C>A p.S1032Y | Missense Mutation (SNP) | VAF 44/606 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.276); called by muse, mutect2
- CECR2 | c.1060A>T p.K354* (on ENST00000342247 / NM_001290047.2; = p.K191* on NM_001290046.1) | Nonsense Mutation (SNP) | VAF 128/522 reads (25%) | called by muse, mutect2, varscan2
- CECR2 | c.1744G>A p.G582R (on ENST00000342247 / NM_001290047.2; = p.G399R on NM_001290046.1) | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- CELSR1 | c.7543C>T p.Q2515* | Nonsense Mutation (SNP) | VAF 42/302 reads (14%) | called by muse, varscan2
- CEP162 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 134/331 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP170B | c.4222G>C p.D1408H (on ENST00000453495; = p.D1337H on NM_015005.3) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- CEP19 | c.319A>G p.K107E | Missense Mutation (SNP) | VAF 139/654 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP46 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 11/126 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.497); called by muse, mutect2
- CHAT | c.1832C>T p.T611I | Missense Mutation (SNP) | VAF 32/307 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.484); called by muse, mutect2, varscan2
- CHD6 | c.1015G>A p.E339K | Missense Mutation (SNP) | VAF 18/522 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2
- CHD9 | c.2596G>T p.E866* | Nonsense Mutation (SNP) | VAF 48/290 reads (17%) | called by muse, mutect2, varscan2
- CIC | c.3760G>T p.E1254* | Nonsense Mutation (SNP) | VAF 5/37 reads (14%) | called by muse, mutect2, varscan2
- CLASP2 | c.2959G>C p.E987Q (on ENST00000359576; = p.E986Q on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- CLK3 | c.915G>C p.E305D (on ENST00000395066 / NM_001130028.1; = p.E157D on NM_003992.4) | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- CNPY3 | c.772C>T p.P258S | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNTN1 | c.2071G>T p.E691* | Nonsense Mutation (SNP) | VAF 112/400 reads (28%) | called by muse, mutect2, varscan2
- COBL | c.2213A>G p.N738S | Missense Mutation (SNP) | VAF 63/183 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- COG4 | c.2286G>C p.W762C | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL11A2 | c.3736G>A p.G1246R (on ENST00000341947 / NM_080680.3; = p.G1139R on NM_080679.2) | Missense Mutation (SNP) | VAF 15/182 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL22A1 | c.2625T>G p.D875E | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- COL4A3 | c.1808C>G p.S603C | Missense Mutation (SNP) | VAF 77/280 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL5A3 | c.3784G>T p.G1262W | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COP1 | c.1730-1G>T p.X577_splice | Splice Site (SNP) | VAF 29/162 reads (18%) | called by muse, mutect2, varscan2
- COPS2 | c.713G>C p.R238T | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, varscan2
- COPS2 | c.624G>C p.Q208H | Missense Mutation (SNP) | VAF 32/322 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.894); called by muse, varscan2
- COQ8A | c.377G>T p.R126I | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- CPD | c.2500C>G p.L834V | Missense Mutation (SNP) | VAF 17/243 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2
- CPS1 | c.2492A>T p.K831I | Missense Mutation (SNP) | VAF 73/585 reads (12%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.645); called by muse, mutect2, varscan2
- CRACD | c.3595A>T p.R1199W | Missense Mutation (SNP) | VAF 32/259 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRIM1 | c.613C>T p.P205S | Missense Mutation (SNP) | VAF 193/412 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSGALNACT2 | c.680G>C p.R227T | Missense Mutation (SNP) | VAF 32/188 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CSH1 | c.457-4del | Splice Region (DEL) | VAF 90/286 reads (31%) | called by mutect2, varscan2
- CSMD1 | c.7507G>T p.G2503* (on ENST00000520002; = p.G2502* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- CSPP1 | c.1645G>T p.A549S (on ENST00000676605; = p.A508S on NM_024790.6) | Missense Mutation (SNP) | VAF 20/361 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.116); called by muse, mutect2
- CSTF1 | c.1295G>C p.*432Sext*25 | Nonstop Mutation (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2, varscan2
- CUBN | c.3700C>T p.H1234Y | Missense Mutation (SNP) | VAF 16/554 reads (3%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.524); called by muse, mutect2
- CUBN | c.548G>T p.S183I | Missense Mutation (SNP) | VAF 129/492 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- CYFIP1 | c.1371G>A p.M457I | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- DACT1 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- DBN1 | c.1747G>T p.G583C | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCC | c.349T>A p.C117S | Missense Mutation (SNP) | VAF 85/433 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCLRE1A | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 10/227 reads (4%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2
- DDX39A | c.1262C>T p.T421I | Missense Mutation (SNP) | VAF 6/101 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.081); called by muse, mutect2
- DDX4 | c.473G>C p.G158A | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DDX46 | c.1308T>G p.D436E | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- DGKG | c.2324C>A p.P775H | Missense Mutation (SNP) | VAF 50/629 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- DGKI | c.2815C>T p.L939F | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DHX33 | c.1680G>A p.M560I | Missense Mutation (SNP) | VAF 15/341 reads (4%) | SIFT tolerated (0.98); PolyPhen benign (0); called by muse, mutect2
- DLGAP2 | c.123C>A p.D41E | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- DNAH11 | c.6196G>A p.G2066R | Missense Mutation (SNP) | VAF 80/341 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.7426C>G p.Q2476E (on ENST00000445597; = p.Q3129E on NM_001367479.1) | Missense Mutation (SNP) | VAF 26/529 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2
- DNAH2 | c.8297G>A p.S2766N | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH8 | c.8780A>G p.H2927R | Missense Mutation (SNP) | VAF 45/206 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH9 | c.4900G>A p.D1634N | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAI4 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.011); called by muse, mutect2
- DNAJA2 | c.592G>A p.E198K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.816); called by muse, mutect2
- DOCK2 | c.3381G>A p.K1127= | Splice Region (SNP) | VAF 28/139 reads (20%) | called by muse, mutect2, varscan2
- DPP6 | c.1761T>A p.N587K (on ENST00000377770 / NM_001364500.2; = p.N525K on NM_001936.5) | Missense Mutation (SNP) | VAF 14/220 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0.013); called by muse, mutect2
- DSCAML1 | c.5892T>A p.Y1964* (on ENST00000321322; = p.Y1904* on NM_020693.4) | Nonsense Mutation (SNP) | VAF 39/178 reads (22%) | called by muse, mutect2, varscan2
- DTNA | c.409G>C p.A137P | Missense Mutation (SNP) | VAF 80/393 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- DYDC1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); called by muse, mutect2
- DYRK4 | c.417G>C p.K139N | Missense Mutation (SNP) | VAF 9/113 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2
- DYTN | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 46/419 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- E2F7 | c.1800G>T p.R600S | Missense Mutation (SNP) | VAF 47/321 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- EML4 | c.1343G>C p.G448A | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EMSY | c.2430G>C p.Q810H | Missense Mutation (SNP) | VAF 15/228 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ESRRG | c.1298A>T p.Q433L | Missense Mutation (SNP) | VAF 181/488 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- FAM111B | c.828G>T p.Q276H | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.041); called by muse, mutect2
- FAM120B | c.2117C>G p.S706* | Nonsense Mutation (SNP) | VAF 20/236 reads (8%) | called by muse, mutect2
- FAM186A | c.5711C>T p.S1904F | Missense Mutation (SNP) | VAF 31/276 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- FAT4 | c.5739C>G p.I1913M | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- FBN1 | c.520G>T p.G174* | Nonsense Mutation (SNP) | VAF 50/617 reads (8%) | called by muse, mutect2
- FBN2 | c.3741G>C p.M1247I | Missense Mutation (SNP) | VAF 82/528 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FBXO2 | c.445G>T p.E149* | Nonsense Mutation (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- FBXO24 | c.31A>T p.R11W | Missense Mutation (SNP) | VAF 76/337 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- FBXO3 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 23/476 reads (5%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.477); called by muse, mutect2
- FBXW12 | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 20/429 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); called by muse, mutect2
- FCGR2C | c.171G>A p.W57* | Nonsense Mutation (SNP) | VAF 46/719 reads (6%) | called by muse, mutect2
- FCN1 | c.341-2A>T p.X114_splice | Splice Site (SNP) | VAF 48/91 reads (53%) | called by muse, mutect2, varscan2
- FCRL3 | c.1737del p.L580Wfs*51 | Frame Shift Del (DEL) | VAF 55/375 reads (15%) | called by mutect2, pindel, varscan2
- FER1L6 | c.3097A>T p.S1033C | Missense Mutation (SNP) | VAF 63/161 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FES | c.95A>T p.K32M | Missense Mutation (SNP) | VAF 61/156 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FGD1 | c.1982C>T p.S661L | Missense Mutation (SNP) | VAF 31/291 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- FGD1 | c.609G>T p.E203D | Missense Mutation (SNP) | VAF 58/105 reads (55%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, varscan2
- FLRT2 | c.1121C>G p.P374R | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated (0.54); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- FNBP1 | c.1318G>C p.D440H | Missense Mutation (SNP) | VAF 22/247 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- FOXRED1 | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 44/480 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- FREM2 | c.9122G>A p.G3041E | Missense Mutation (SNP) | VAF 18/526 reads (3%) | SIFT tolerated (0.46); PolyPhen benign (0.012); called by muse, mutect2
- FRY | c.2793G>C p.M931I | Missense Mutation (SNP) | VAF 27/303 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.148); called by muse, mutect2
- FRYL | c.5171A>T p.N1724I | Missense Mutation (SNP) | VAF 100/504 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- FSHB | c.-5C>T | Splice Region (SNP) | VAF 66/534 reads (12%) | called by muse, mutect2, varscan2
- FSIP1 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.329); called by muse, mutect2
- FUT9 | c.724C>A p.L242I | Missense Mutation (SNP) | VAF 8/128 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FYB1 | c.1408G>C p.E470Q | Missense Mutation (SNP) | VAF 26/832 reads (3%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); called by muse, mutect2
- GAB2 | c.541C>T p.Q181* (on ENST00000361507 / NM_080491.3; = p.Q143* on NM_012296.3) | Nonsense Mutation (SNP) | VAF 139/484 reads (29%) | called by muse, mutect2, varscan2
- GAB3 | c.515G>A p.R172K | Missense Mutation (SNP) | VAF 24/366 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.15); called by muse, mutect2
- GALNT13 | c.657G>T p.E219D | Missense Mutation (SNP) | VAF 19/384 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- GART | c.2845G>C p.D949H | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); called by muse, mutect2
- GDPD5 | c.796A>G p.S266G | Missense Mutation (SNP) | VAF 39/147 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- GET4 | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- GFRA4 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GGCX | c.2207C>T p.P736L | Missense Mutation (SNP) | VAF 21/576 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2
- GLRA1 | c.1228G>A p.E410K (on ENST00000455880 / NM_001146040.2; = p.E402K on NM_000171.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/434 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.595); called by muse, mutect2
- GLYATL3 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 85/262 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.28); called by muse, mutect2, varscan2
- GPAM | c.2044G>A p.E682K | Missense Mutation (SNP) | VAF 22/436 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.025); called by muse, mutect2
- GSE1 | c.315G>A p.M105I | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- GSPT1 | c.145G>A p.E49K (on ENST00000420576 / NM_001130007.2; = p.E187K on NM_002094.4) | Missense Mutation (SNP) | VAF 62/656 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.202); called by muse, mutect2
- GTPBP3 | c.984G>T p.Q328H | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); called by muse, mutect2
- H3C7 | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 10/199 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); called by muse, mutect2
- HAPLN1 | c.1049T>G p.F350C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- HCN4 | c.2552C>G p.T851R | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- HDAC1 | c.568A>T p.T190S | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- HEATR9 | c.424C>T p.Q142* | Nonsense Mutation (SNP) | VAF 12/270 reads (4%) | called by muse, mutect2
- HIVEP2 | c.7316C>T p.S2439L | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2
- HMGN3 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 56/194 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- HNRNPUL2 | c.1309G>C p.E437Q | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2
- HOGA1 | c.652C>T p.Q218* | Nonsense Mutation (SNP) | VAF 13/287 reads (5%) | called by muse, mutect2
- HOXC10 | c.658C>G p.L220V | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2
- HSPA9 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 26/288 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.087); called by muse, mutect2
- HSPBP1 | c.509G>T p.G170V | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- HSPBP1 | c.508G>C p.G170R | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR1B | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 48/114 reads (42%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HTR1F | c.263G>A p.S88N | Missense Mutation (SNP) | VAF 13/348 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2
- HTRA3 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ICE1 | c.1298A>T p.E433V | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- IER3 | c.211-5C>A | Splice Region (SNP) | VAF 96/239 reads (40%) | called by muse, mutect2, varscan2
- IFNA16 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 13/218 reads (6%) | called by muse, mutect2
- IGF2BP1 | c.907G>C p.E303Q | Missense Mutation (SNP) | VAF 23/295 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.098); called by muse, mutect2
- IGFN1 | c.1630C>A p.P544T (on ENST00000295591 / NM_001367841.1; = p.P3001T on NM_001164586.2) | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IGHV4-34 | c.22A>T p.M8L | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- IGKV3-15 | c.131G>T p.R44M | Missense Mutation (SNP) | VAF 63/663 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.173); called by muse, mutect2
- IGLV1-47 | c.119C>A p.S40Y | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- IGLV3-16 | c.108G>T p.M36I | Missense Mutation (SNP) | VAF 68/248 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IMPG1 | c.378G>T p.W126C | Missense Mutation (SNP) | VAF 62/426 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA7 | c.220G>C p.A74P | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ITGA9 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 17/153 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- ITGAV | c.1255C>G p.Q419E | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2
- ITPR1 | c.6278C>T p.S2093L (on ENST00000354582; = p.S2038L on NM_002222.7) | Missense Mutation (SNP) | VAF 8/162 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- JMY | c.2255C>T p.P752L | Missense Mutation (SNP) | VAF 73/320 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- JPH2 | c.2090G>C p.*697Sext*11 | Nonstop Mutation (SNP) | VAF 28/312 reads (9%) | called by muse, mutect2
- KANSL1 | c.2380G>C p.E794Q | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.962); called by muse, mutect2
- KCNC2 | c.560C>A p.A187D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- KCNH7 | c.1484G>T p.G495V | Missense Mutation (SNP) | VAF 41/232 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KDM2B | c.1675G>C p.D559H | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- KEAP1 | c.757G>T p.V253F | Missense Mutation (SNP) | VAF 33/139 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- KIAA1109 | c.12656G>A p.G4219E | Missense Mutation (SNP) | VAF 28/409 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); called by muse, mutect2
- KIAA2026 | c.4591C>G p.L1531V | Missense Mutation (SNP) | VAF 22/340 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.297); called by muse, mutect2
- KIF4B | c.2213G>T p.G738V | Missense Mutation (SNP) | VAF 126/507 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- KIRREL2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated (0.93); PolyPhen possibly damaging (0.583); called by muse, mutect2
- KL | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KLHL32 | c.1267A>T p.K423* | Nonsense Mutation (SNP) | VAF 114/439 reads (26%) | called by muse, mutect2, varscan2
- KLRC1 | c.554C>A p.P185Q | Missense Mutation (SNP) | VAF 82/306 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, varscan2
- KMT2A | c.3424C>T p.Q1142* | Nonsense Mutation (SNP) | VAF 24/564 reads (4%) | called by muse, mutect2
- KMT2B | c.3936G>C p.K1312N | Missense Mutation (SNP) | VAF 14/279 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- KMT2E | c.2954C>G p.S985C | Missense Mutation (SNP) | VAF 18/154 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.887); called by muse, mutect2
- KMT5B | c.439G>C p.D147H | Missense Mutation (SNP) | VAF 19/255 reads (7%) | SIFT tolerated (0.82); PolyPhen benign (0.025); called by muse, mutect2
- KPNB1 | c.1913-4A>T | Splice Region (SNP) | VAF 46/239 reads (19%) | called by muse, mutect2, varscan2
- KRTAP10-10 | c.674C>G p.S225C | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LGALS3BP | c.1136_1138delinsTT p.Q379Lfs*19 | Frame Shift Del (DEL) | VAF 23/94 reads (24%) | called by pindel, varscan2*
- LIPN | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 16/228 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2
- LKAAEAR1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.88); PolyPhen benign (0); called by muse, mutect2, varscan2
- LOXL1 | c.733G>C p.E245Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- LPIN2 | c.1067C>T p.S356L | Missense Mutation (SNP) | VAF 42/365 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC53 | c.539T>C p.L180P | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LRRC8B | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 12/302 reads (4%) | called by muse, mutect2
- LRRC9 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 12/207 reads (6%) | called by muse, mutect2
- LRRTM1 | c.355A>T p.T119S | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.236); called by muse, mutect2, varscan2
- LTBP2 | c.1367C>G p.S456C | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- LY6G6C | c.29C>G p.S10C | Missense Mutation (SNP) | VAF 8/200 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- LY9 | c.596C>T p.S199F | Missense Mutation (SNP) | VAF 19/606 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2
- LYPD4 | c.67+2T>A p.X23_splice | Splice Site (SNP) | VAF 33/216 reads (15%) | called by muse, mutect2, varscan2
- LZTS1 | c.1397A>G p.E466G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- MAB21L4 | c.1263C>G p.F421L (on ENST00000388934 / NM_001085437.3; = p.F253L on NM_024861.4) | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2
- MAGEA11 | c.340G>C p.E114Q | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.794); called by muse, mutect2, varscan2
- MAL | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- MALRD1 | c.3719A>C p.Y1240S | Missense Mutation (SNP) | VAF 75/220 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- MAML2 | c.1775A>T p.Q592L | Missense Mutation (SNP) | VAF 235/789 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.076); called by muse, varscan2
- MAP3K11 | c.1490-1G>C p.X497_splice | Splice Site (SNP) | VAF 10/184 reads (5%) | called by muse, mutect2
- MAP4K5 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 13/283 reads (5%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); called by muse, mutect2
- MAPK4 | c.1226T>A p.L409Q | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- MAPKAPK3 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 25/405 reads (6%) | called by muse, mutect2
- MAPKBP1 | c.469G>A p.D157N | Missense Mutation (SNP) | VAF 10/156 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2
- MARVELD2 | c.272G>C p.R91T | Missense Mutation (SNP) | VAF 10/174 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.425); called by muse, mutect2
- MBTD1 | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 22/630 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- MC3R | c.218T>A p.M73K | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MED1 | c.674A>T p.Y225F | Missense Mutation (SNP) | VAF 45/244 reads (18%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MKI67 | c.4274G>A p.G1425E | Missense Mutation (SNP) | VAF 22/302 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2
- MMP16 | c.965G>T p.R322M | Missense Mutation (SNP) | VAF 36/554 reads (6%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.96); called by muse, mutect2
- MMP16 | c.385C>A p.H129N | Missense Mutation (SNP) | VAF 61/245 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MMP28 | c.722A>T p.E241V | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MMP28 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 33/126 reads (26%) | called by muse, mutect2, varscan2
- MOBP | c.48del p.K17Sfs*23 | Frame Shift Del (DEL) | VAF 49/329 reads (15%) | called by mutect2, pindel, varscan2
- MOCS1 | c.1406C>T p.S469F | Missense Mutation (SNP) | VAF 33/415 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.001); called by muse, mutect2
- MS4A18 | c.634C>T p.P212S (on ENST00000398983; = p.P214S on NM_001354471.1) | Missense Mutation (SNP) | VAF 84/317 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MTHFD1L | c.1287G>C p.K429N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- MTMR1 | c.847C>T p.R283* | Nonsense Mutation (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- MTUS1 | c.1521C>G p.F507L | Missense Mutation (SNP) | VAF 54/344 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- MUC16 | c.16796A>C p.Q5599P | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- MUC16 | c.8602A>T p.S2868C | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- MUC17 | c.12113C>A p.T4038N | Missense Mutation (SNP) | VAF 91/302 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- MVB12B | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 10/265 reads (4%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2
- MXRA5 | c.950G>C p.S317T | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH11 | c.5214C>G p.I1738M | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MYLK | c.1505T>A p.L502H | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MYO15A | c.9313G>A p.D3105N | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.28); called by muse, mutect2
- MYO5C | c.3067G>C p.E1023Q | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.501); called by muse, mutect2
- NCSTN | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 24/711 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.893); called by muse, mutect2
- NDUFA11 | c.187del p.A63Qfs*26 | Frame Shift Del (DEL) | VAF 44/254 reads (17%) | called by mutect2, pindel, varscan2
- NDUFV1 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- NEB | c.8812G>C p.D2938H | Missense Mutation (SNP) | VAF 20/371 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.877); called by muse, mutect2
- NEK1 | c.2658G>T p.L886F | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.391); called by muse, mutect2
- NEO1 | c.1146C>G p.I382M | Missense Mutation (SNP) | VAF 59/196 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NFAT5 | c.3016C>T p.Q1006* | Nonsense Mutation (SNP) | VAF 17/352 reads (5%) | called by muse, mutect2
- NLRP13 | c.2818G>T p.G940C | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- NME8 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 122/592 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NMI | c.841C>T p.Q281* | Nonsense Mutation (SNP) | VAF 26/338 reads (8%) | called by muse, mutect2
- NPR2 | c.715C>G p.Q239E | Missense Mutation (SNP) | VAF 28/502 reads (6%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- NQO2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.151); called by muse, mutect2
- NR6A1 | c.1198C>T p.Q400* (on ENST00000487099 / NM_033334.4; = p.Q395* on NM_001489.5) | Nonsense Mutation (SNP) | VAF 11/176 reads (6%) | called by muse, mutect2
- NRROS | c.-12G>T | Splice Region (SNP) | VAF 124/567 reads (22%) | called by muse, mutect2, varscan2
- NRXN1 | c.2627G>A p.G876E | Missense Mutation (SNP) | VAF 16/444 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2
- NRXN2 | c.3420C>G p.I1140M | Missense Mutation (SNP) | VAF 19/303 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); called by muse, mutect2
- NSD1 | c.5945G>A p.R1982K | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.113); called by muse, mutect2
- NTAQ1 | c.478C>G p.P160A | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.136); called by muse, mutect2
- NTN1 | c.1776C>G p.F592L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.083); called by mutect2, varscan2
- NUDCD1 | c.1432dup p.E478Gfs*35 | Frame Shift Ins (INS) | VAF 73/238 reads (31%) | called by mutect2, pindel, varscan2
- NUDT16L1 | c.80C>G p.S27W | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by mutect2, varscan2
- NVL | c.2497A>T p.K833* | Nonsense Mutation (SNP) | VAF 103/323 reads (32%) | called by muse, mutect2, varscan2
- NXN | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.36); PolyPhen benign (0.079); called by muse, mutect2
- NXPH3 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OBP2B | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 11/222 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.455); called by muse, mutect2
- OBSCN | c.17623G>A p.E5875K | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- OPA1 | c.1642A>C p.M548L (on ENST00000361510 / NM_130837.3; = p.M493L on NM_015560.3) | Missense Mutation (SNP) | VAF 34/532 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); called by muse, mutect2
- OR10A5 | c.95T>A p.F32Y | Missense Mutation (SNP) | VAF 115/395 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- OR2AP1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2F2 | c.760A>G p.T254A | Missense Mutation (SNP) | VAF 14/172 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.034); called by muse, mutect2
- OR4C15 | c.769G>T p.G257W (on ENST00000314644; = p.G203W on NM_001001920.2) | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR56B1 | c.817A>T p.T273S | Missense Mutation (SNP) | VAF 63/251 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- P2RX1 | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.033); called by muse, mutect2
- PAPLN | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- PAQR6 | c.168C>A p.F56L | Missense Mutation (SNP) | VAF 11/231 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.405); called by muse, mutect2
- PARP15 | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 31/456 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); called by muse, mutect2
- PAX4 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 117/391 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- PCDHGA3 | c.1091G>A p.R364K | Missense Mutation (SNP) | VAF 11/115 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.193); called by muse, mutect2
- PCLO | c.5194A>G p.T1732A | Missense Mutation (SNP) | VAF 105/511 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- PGM3 | c.29C>T p.S10L | Missense Mutation (SNP) | VAF 36/576 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.816); called by muse, mutect2
- PGM5 | c.925G>T p.V309L | Missense Mutation (SNP) | VAF 120/470 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- PGR | c.2087C>A p.P696Q | Missense Mutation (SNP) | VAF 114/486 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHB2 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- PIK3AP1 | c.709C>T p.P237S | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKHD1 | c.8174-2A>G p.X2725_splice | Splice Site (SNP) | VAF 218/647 reads (34%) | called by muse, mutect2, varscan2
- PLA2R1 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 10/193 reads (5%) | SIFT tolerated (0.76); PolyPhen benign (0.096); called by muse, mutect2
- PLAAT4 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 28/471 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLCD1 | c.431G>C p.W144S | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PLCL2 | c.3351A>G p.I1117M (on ENST00000615277 / NM_001144382.2; = p.I991M on NM_015184.5) | Missense Mutation (SNP) | VAF 52/160 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- PLEKHA4 | c.384G>A p.M128I | Missense Mutation (SNP) | VAF 13/107 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- PLG | c.2123A>T p.Q708L | Missense Mutation (SNP) | VAF 17/256 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- PLXNA2 | c.2755G>T p.G919C | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- PODN | c.1162del p.L388Cfs*47 (on ENST00000395871; = p.L340Cfs*47 on NM_153703.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 40/108 reads (37%) | called by mutect2, pindel, varscan2
- POTEA | c.450G>T p.M150I | Missense Mutation (SNP) | VAF 30/125 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEB3 | c.72G>T p.M24I | Missense Mutation (SNP) | VAF 69/749 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); called by muse, varscan2
- PPM1B | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- PPM1E | c.1904C>A p.T635K | Missense Mutation (SNP) | VAF 41/228 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP2R1B | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.015); called by muse, mutect2
- PRAMEF18 | c.566C>G p.S189* | Nonsense Mutation (SNP) | VAF 28/468 reads (6%) | called by muse, mutect2
- PRKAR2B | c.331A>T p.R111W | Missense Mutation (SNP) | VAF 66/288 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, varscan2
- PRKAR2B | c.1003G>A p.E335K | Missense Mutation (SNP) | VAF 17/196 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.281); called by muse, mutect2
- PROSER1 | c.1751G>T p.G584V | Missense Mutation (SNP) | VAF 62/297 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PRPF40A | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); called by muse, mutect2
- PRRC2C | c.6250G>A p.E2084K (on ENST00000367742; = p.E2082K on NM_015172.4) | Missense Mutation (SNP) | VAF 21/378 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2
- PRSS41 | c.359C>A p.S120Y | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.083); called by muse, mutect2
- PRUNE1 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.09); called by muse, varscan2
- PRXL2A | c.503G>C p.G168A | Missense Mutation (SNP) | VAF 28/331 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- PSIP1 | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- PSMD10 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 72/140 reads (51%) | SIFT tolerated (0.49); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- PTCD3 | c.2066A>T p.K689I | Missense Mutation (SNP) | VAF 86/333 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRB | c.4730A>G p.Y1577C | Missense Mutation (SNP) | VAF 72/164 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PTPRB | c.144G>C p.Q48H | Missense Mutation (SNP) | VAF 21/253 reads (8%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.005); called by muse, mutect2
- PTPRC | c.1794_1795del p.Y599Qfs*4 | Frame Shift Del (DEL) | VAF 126/438 reads (29%) | called by pindel, varscan2
- RAB40A | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 7/100 reads (7%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.67); called by muse, mutect2
- RAB8B | c.404G>C p.R135T | Missense Mutation (SNP) | VAF 34/416 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.068); called by muse, mutect2
- RAB9B | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 12/260 reads (5%) | SIFT tolerated (0.85); PolyPhen benign (0.046); called by muse, mutect2
- RABEP1 | c.1901C>T p.S634L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RAPH1 | c.1663G>C p.D555H (on ENST00000319170 / NM_213589.3; = p.D607H on NM_203365.4) | Missense Mutation (SNP) | VAF 24/309 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- RASSF6 | c.678T>G p.I226M (on ENST00000342081 / NM_201431.2; = p.I194M on NM_177532.5) | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- RBM47 | c.690G>A p.W230* | Nonsense Mutation (SNP) | VAF 28/194 reads (14%) | called by muse, mutect2, varscan2
- RFPL2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 24/398 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.011); called by muse, mutect2
- RGS11 | c.145C>T p.P49S (on ENST00000397770 / NM_183337.3; = p.P28S on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- RHAG | c.895A>T p.I299F | Missense Mutation (SNP) | VAF 245/774 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- RNF34 | c.1059G>C p.M353I | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- ROR1 | c.356G>C p.R119T | Missense Mutation (SNP) | VAF 36/369 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.21); called by muse, mutect2
- RTF2 | c.399-1G>T p.X133_splice | Splice Site (SNP) | VAF 42/257 reads (16%) | called by muse, mutect2, varscan2
- RTP5 | c.394C>G p.P132A | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.048); called by muse, mutect2
- RUNX1T1 | c.1347T>A p.A449= (on ENST00000265814 / NM_001198628.1; = p.A422= on NM_004349.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 9/246 reads (4%) | called by muse, mutect2
- RYR1 | c.3757C>T p.H1253Y | Missense Mutation (SNP) | VAF 18/456 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.418); called by muse, mutect2
- RYR2 | c.1732G>T p.V578F | Missense Mutation (SNP) | VAF 61/356 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- SAMM50 | c.1199G>C p.G400A | Missense Mutation (SNP) | VAF 25/229 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SAP130 | c.2834G>A p.G945D | Missense Mutation (SNP) | VAF 17/303 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- SBSN | c.950G>A p.G317E | Missense Mutation (SNP) | VAF 87/255 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- SCN4A | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, varscan2
- SCN8A | c.5482G>C p.E1828Q | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- SCUBE1 | c.2544G>C p.E848D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); called by muse, mutect2
- SEC62 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 43/890 reads (5%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SELE | c.1042G>C p.E348Q | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.993); called by muse, mutect2
- SEMA4F | c.1787G>T p.C596F | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- SEPTIN14 | c.948G>A p.M316I | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); called by muse, varscan2
- SERPINI2 | c.776T>C p.I259T | Missense Mutation (SNP) | VAF 100/457 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- SETD4 | c.235G>A p.E79K | Missense Mutation (SNP) | VAF 28/336 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.16); called by muse, mutect2
- SF3B1 | c.3539G>A p.R1180K | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SH2B2 | c.1027G>A p.D343N | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- SH2B2 | c.1556A>T p.Q519L | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- SHC4 | c.5G>T p.R2L | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SHISA2 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); called by muse, mutect2
- SHISA9 | c.1133T>A p.L378H | Missense Mutation (SNP) | VAF 44/220 reads (20%) | SIFT tolerated (0.47); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- SIRT2 | c.586G>T p.V196F | Missense Mutation (SNP) | VAF 58/155 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- SKOR2 | c.1896C>G p.D632E | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- SLAMF7 | c.196G>C p.E66Q | Missense Mutation (SNP) | VAF 53/612 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.024); called by muse, mutect2
- SLC12A5 | c.1474G>A p.A492T (on ENST00000454036 / NM_001134771.2; = p.A469T on NM_020708.5) | Missense Mutation (SNP) | VAF 25/180 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- SLC28A1 | c.58G>T p.G20C | Missense Mutation (SNP) | VAF 39/239 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- SLC39A11 | c.73G>A p.G25R | Missense Mutation (SNP) | VAF 26/323 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLIT1 | c.1049C>A p.P350H | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.974); called by muse, varscan2
- SLITRK5 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 15/324 reads (5%) | SIFT tolerated (0.82); PolyPhen benign (0.262); called by muse, mutect2
- SMURF1 | c.1372C>T p.P458S | Missense Mutation (SNP) | VAF 22/412 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNAP91 | c.2331G>A p.K777= | Splice Region (SNP) | VAF 100/789 reads (13%) | called by muse, mutect2, varscan2
- SNCAIP | c.1667C>T p.S556L | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.186); called by muse, mutect2
- SORT1 | c.250G>T p.E84* | Nonsense Mutation (SNP) | VAF 8/44 reads (18%) | called by muse, varscan2
- SP4 | c.1954G>A p.E652K | Missense Mutation (SNP) | VAF 14/323 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.669); called by muse, mutect2
- SPAG17 | c.2356G>A p.E786K | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- SPARCL1 | c.1894G>C p.E632Q | Missense Mutation (SNP) | VAF 17/398 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.096); called by muse, mutect2
- SPECC1L | c.1213G>C p.E405Q | Missense Mutation (SNP) | VAF 26/470 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SPTBN2 | c.3589C>T p.H1197Y | Missense Mutation (SNP) | VAF 16/438 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- SRRM2 | c.1842G>C p.R614S | Missense Mutation (SNP) | VAF 32/172 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- SSH3 | c.1525G>A p.E509K | Missense Mutation (SNP) | VAF 7/166 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.056); called by muse, mutect2
- ST8SIA3 | c.641T>C p.I214T | Missense Mutation (SNP) | VAF 49/301 reads (16%) | PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- STARD7 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 24/374 reads (6%) | called by muse, mutect2
- STAT2 | c.2546C>T p.S849F | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- STAT3 | c.445C>T p.Q149* | Nonsense Mutation (SNP) | VAF 34/600 reads (6%) | called by muse, mutect2
- STRBP | c.1231G>A p.G411S | Missense Mutation (SNP) | VAF 233/547 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- STRN4 | c.418G>C p.D140H | Missense Mutation (SNP) | VAF 16/408 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2
- STXBP5 | c.1573G>A p.V525I | Missense Mutation (SNP) | VAF 20/264 reads (8%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.985); called by muse, mutect2
- SULT1B1 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 43/169 reads (25%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SUPT6H | c.1279C>G p.Q427E | Missense Mutation (SNP) | VAF 88/375 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SVOPL | c.17C>A p.T6K | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); called by muse, mutect2
- SYTL1 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 22/132 reads (17%) | called by muse, mutect2, varscan2
- TAAR2 | c.672G>T p.M224I (on ENST00000367931 / NM_001033080.1; = p.M179I on NM_014626.3) | Missense Mutation (SNP) | VAF 79/371 reads (21%) | SIFT tolerated (0.91); PolyPhen benign (0); called by muse, mutect2, varscan2
- TBC1D4 | c.2224G>A p.D742N | Missense Mutation (SNP) | VAF 44/626 reads (7%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2
- TDRD6 | c.2882A>T p.K961I | Missense Mutation (SNP) | VAF 36/154 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- TENM1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 19/308 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.211); called by muse, mutect2
- TEX13C | c.734C>G p.S245* | Nonsense Mutation (SNP) | VAF 24/152 reads (16%) | called by muse, mutect2, varscan2
- THEGL | c.343del p.A115Pfs*30 | Frame Shift Del (DEL) | VAF 23/120 reads (19%) | called by mutect2, pindel, varscan2
- THEGL | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 8/105 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TIFA | c.181C>G p.Q61E | Missense Mutation (SNP) | VAF 18/171 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TIMM10 | c.124G>C p.E42Q | Missense Mutation (SNP) | VAF 31/420 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.578); called by muse, mutect2
- TLE4 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 18/279 reads (6%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.928); called by muse, mutect2
- TMEM108 | c.1663G>C p.V555L | Missense Mutation (SNP) | VAF 46/346 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMEM151A | c.1389T>A p.D463E | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- TMEM163 | c.621G>C p.K207N | Missense Mutation (SNP) | VAF 29/314 reads (9%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2
- TMEM181 | c.866C>T p.S289F | Missense Mutation (SNP) | VAF 44/194 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- TMEM267 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 78/375 reads (21%) | SIFT tolerated (0.5); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- TMEM67 | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 30/268 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.428); called by muse, varscan2
- TMTC1 | c.92C>A p.A31E | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- TNN | c.563G>T p.C188F | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, varscan2
- TRAC | c.413T>C p.L138P | Missense Mutation (SNP) | VAF 24/236 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAP1 | c.64C>G p.P22A | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.066); called by muse, mutect2
- TRIM24 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 9/140 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- TRIM37 | c.436G>C p.E146Q | Missense Mutation (SNP) | VAF 40/439 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.241); called by muse, mutect2
- TRIM64 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 30/188 reads (16%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by mutect2, varscan2
- TRIP11 | c.315A>G p.V105= | Splice Region (SNP) | VAF 18/298 reads (6%) | called by muse, mutect2
- TRMT5 | c.1285G>A p.E429K | Missense Mutation (SNP) | VAF 22/394 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TRRAP | c.2375T>G p.M792R | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTC13 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 95/392 reads (24%) | SIFT tolerated (0.38); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- TTC39C | c.1623G>C p.E541D (on ENST00000317571 / NM_001135993.2; = p.E480D on NM_153211.4) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2
- TTN | c.29728G>A p.E9910K (on ENST00000591111; = p.E8983K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/350 reads (7%) | PolyPhen probably damaging (0.953); called by muse, mutect2
- TUBE1 | c.1251G>C p.M417I | Missense Mutation (SNP) | VAF 9/120 reads (8%) | SIFT tolerated (0.46); PolyPhen benign (0.006); called by muse, mutect2
- TXNRD2 | c.1048T>A p.S350T | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.029); called by muse, mutect2
- UBA7 | c.2773G>C p.E925Q | Missense Mutation (SNP) | VAF 14/117 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- UBR3 | c.5494T>C p.C1832R | Missense Mutation (SNP) | VAF 114/428 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- UBR5 | c.4278G>T p.M1426I | Missense Mutation (SNP) | VAF 14/154 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2
- UNC13A | c.870del p.D291Tfs*74 | Frame Shift Del (DEL) | VAF 18/104 reads (17%) | called by pindel, varscan2
- UNC80 | c.5808C>G p.I1936M | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.788); called by muse, mutect2
- UQCC1 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 22/343 reads (6%) | SIFT tolerated (0.76); PolyPhen benign (0.057); called by muse, mutect2
- USF1 | c.890G>T p.R297L | Missense Mutation (SNP) | VAF 110/351 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- USP21 | c.109G>C p.E37Q | Missense Mutation (SNP) | VAF 25/493 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2
- USP34 | c.1996G>A p.G666R | Missense Mutation (SNP) | VAF 54/948 reads (6%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.02); called by muse, mutect2
484 further variants in this file (45 protein-altering or splice-affecting, 260 silent, 179 other) are not listed here.
